Somatic mutation profile of tumor specimen TCGA-SN-A84Y-01A (aliquot TCGA-SN-A84Y-01A-11D-A435-10) from TCGA case TCGA-SN-A84Y, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 18.6 years (6,805 days).
Specimen TCGA-SN-A84Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 499c235b-fd66-436e-b6ec-c32389cb29a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SN-A84Y-10A (Blood Derived Normal), aliquot TCGA-SN-A84Y-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10fdddaa-2519-4c20-87bc-5c661183868b

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Del 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF4G3 | c.4706C>G p.T1569R | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs762356088; called by muse, mutect2, varscan2
- PCLO | c.7575A>C p.K2525N | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV61632931, COSV61638903; called by muse, mutect2, varscan2
- SRCAP | c.7630C>T p.P2544S | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99350124; called by muse, mutect2, varscan2
- TMEM132D | c.631G>C p.G211R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV70594541, COSV70604549; called by muse, mutect2, varscan2
- ALDH18A1 | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.101); called by muse, mutect2
- CTNND1 | c.1762_1766del p.Y588Sfs*38 (on ENST00000399050 / NM_001085458.2; = p.Y588Sfs*53 on NM_001331.3) | Frame Shift Del (DEL) | VAF 27/78 reads (35%) | called by pindel, varscan2
- FIG4 | c.2377-7A>T | Splice Region (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- KLF3 | c.845G>T p.R282I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MEIOC | c.736_739del p.N246Vfs*34 | Frame Shift Del (DEL) | VAF 36/148 reads (24%) | called by mutect2, pindel, varscan2
- PHC1 | c.1736C>G p.P579R | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNMT1 | c.2262G>T p.A754= | Silent (SNP) | VAF 73/176 reads (41%) | catalogued as rs771365059, COSV61582980; called by muse, mutect2, varscan2
- MARS1 | c.1338G>C p.S446= | Silent (SNP) | VAF 19/186 reads (10%) | catalogued as rs781410179; called by muse, mutect2
- SPZ1 | c.861C>G p.V287= | Silent (SNP) | VAF 84/315 reads (27%) | catalogued as COSV57064885; called by muse, mutect2, varscan2
- THAP7 | chr22:21002826 A>G | 5'Flank (SNP) | VAF 3/18 reads (17%) | catalogued as rs1299750551; called by muse, mutect2
